Gene-level copy-number profile of tumor specimen C3N-03027-01 from CPTAC case C3N-03027, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.4 years (23,896 days).
Specimen C3N-03027-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b169af98-b44e-4baa-9624-e66dac1914df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03027-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/7b254f40-67e0-4bef-835e-3e9356c111f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 514; copy number 1: 1,174; copy number 2: 43,928; copy number 3: 7,087; copy number 4: 4,955; copy number 5: 190; copy number 6: 709; copy number 7: 84; copy number 9: 208; copy number 12: 31; copy number 16: 35.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,255 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:143,855,739–198,123,232, 917 genes, copy number 6–9 (broad region; genes not listed).
- chr11:69,294,151–71,670,297, 64 genes, copy number 12–16 (broad region; genes not listed).
- chr11:71,690,453–71,705,404, 2 genes, copy number 12: SNRPCP14, AP003498.1.
- chr17:26,981,694–30,236,002, 179 genes, copy number 5 (broad region; genes not listed).
- chr17:37,514,807–39,864,312, 93 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
